Somatic mutation profile of tumor specimen TARGET-30-PAISSH-01A (aliquot TARGET-30-PAISSH-01A-01W) from TARGET case TARGET-30-PAISSH, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Age at diagnosis: 1.8 years (656 days).
Specimen TARGET-30-PAISSH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 23bfdbe5-feec-40ad-ba63-6e9a3c290d83.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAISSH-10A (Blood Derived Normal), aliquot TARGET-30-PAISSH-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0832f664-7b6f-472f-b8e8-c6d7e5484fed

The open-access MAF lists 70 somatic variants for this specimen: 43 protein-altering or splice-affecting, 25 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 25, Nonsense Mutation 3, 3'Flank 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AK9 | c.5689T>A p.L1897I | Missense Mutation (SNP) | VAF 66/543 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV69852952; called by muse, mutect2, varscan2
- CACNA1H | c.5021G>A p.R1674H | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs369914175; called by muse, mutect2, varscan2
- CECR2 | c.1523G>A p.R508K (on ENST00000342247 / NM_001290047.2; = p.R325K on NM_001290046.1) | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV52846296; called by muse, mutect2, varscan2
- CFAP94 | c.568C>A p.Q190K (on ENST00000320267 / NM_001352064.2; = p.Q196K on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/299 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0.084); catalogued as rs1460787821, COSV57229600; called by muse, mutect2
- CLASP2 | c.2501G>A p.R834K | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.684); catalogued as COSV56286905, COSV56290850; called by muse, mutect2, varscan2
- CTDNEP1 | c.301A>C p.K101Q | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.062); catalogued as COSV56642724; called by muse, mutect2, varscan2
- DDI1 | c.214G>A p.V72M | Missense Mutation (SNP) | VAF 51/304 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs770274476, COSV56381028; called by muse, mutect2, varscan2
- EVC | c.1754A>G p.E585G | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as rs573432745, COSV53836785; called by muse, mutect2, varscan2
- GLDN | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.964); catalogued as COSV100118092; called by muse, mutect2
- GLRA4 | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 79/488 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65456680; called by muse, mutect2, varscan2
- GPC4 | c.1276G>C p.G426R | Missense Mutation (SNP) | VAF 48/435 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63699193; called by muse, mutect2, varscan2
- HPCA | c.224A>G p.N75S | Missense Mutation (SNP) | VAF 131/371 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV65103236; called by muse, mutect2, varscan2
- LRP3 | c.272T>G p.F91C | Missense Mutation (SNP) | VAF 26/201 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53506618; called by muse, mutect2, varscan2
- N6AMT1 | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 47/304 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as COSV58135499; called by muse, mutect2, varscan2
- POF1B | c.660T>A p.N220K | Missense Mutation (SNP) | VAF 88/223 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV53138795; called by muse, mutect2, varscan2
- PRPS2 | c.588G>T p.R196S | Missense Mutation (SNP) | VAF 113/630 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV66180100; called by muse, mutect2, varscan2
- PTPRM | c.134A>G p.D45G | Missense Mutation (SNP) | VAF 49/423 reads (12%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.987); catalogued as COSV59875617; called by muse, mutect2, varscan2
- RORC | c.112T>C p.S38P | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59094907; called by muse, mutect2, varscan2
- SLC2A4 | c.1192G>T p.G398C | Missense Mutation (SNP) | VAF 39/230 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50301919; called by muse, mutect2, varscan2
- SLC9A1 | c.2279G>A p.G760E | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV56055659; called by muse, mutect2, varscan2
- SYNE2 | c.16265C>A p.A5422E | Missense Mutation (SNP) | VAF 70/218 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.046); catalogued as COSV59964347; called by muse, mutect2, varscan2
- TRA2B | c.656G>T p.R219L | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV52025568; called by muse, mutect2, varscan2
- TRIT1 | c.1192G>C p.D398H | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.2); catalogued as COSV57549613; called by muse, mutect2, varscan2
- TRPM6 | c.3285C>A p.Y1095* | Nonsense Mutation (SNP) | VAF 15/117 reads (13%) | catalogued as COSV62509592; called by muse, mutect2, varscan2
- TTLL1 | c.1243G>C p.G415R | Missense Mutation (SNP) | VAF 60/248 reads (24%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV56740189; called by muse, mutect2, varscan2
- USH2A | c.11470G>T p.G3824C | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV56416950; called by muse, mutect2
- WAC | c.58G>A p.G20R | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.021); catalogued as COSV61569205; called by muse, mutect2, varscan2
- ZNF134 | c.1086C>A p.H362Q | Missense Mutation (SNP) | VAF 31/299 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV68696754; called by muse, mutect2, varscan2
- ZNF503 | c.997G>C p.G333R | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65307722; called by muse, mutect2, varscan2
- ZNF711 | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV52157727; called by muse, mutect2, varscan2
- ZNF780B | c.626C>T p.T209I | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.665); catalogued as COSV55464497; called by muse, mutect2, varscan2
- AVIL | c.439G>T p.A147S | Missense Mutation (SNP) | VAF 34/400 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- CLPTM1L | c.1129C>A p.L377M | Missense Mutation (SNP) | VAF 24/217 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- CWC25 | c.677G>T p.G226V | Missense Mutation (SNP) | VAF 13/206 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- GGCX | c.1797C>A p.Y599* | Nonsense Mutation (SNP) | VAF 67/667 reads (10%) | called by muse, mutect2
- ITGA4 | c.1512T>A p.Y504* | Nonsense Mutation (SNP) | VAF 29/378 reads (8%) | called by muse, mutect2
- MED13 | c.1173-1G>A p.X391_splice | Splice Site (SNP) | VAF 9/95 reads (9%) | called by muse, mutect2
- OR4D2 | c.210C>A p.D70E | Missense Mutation (SNP) | VAF 42/706 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.115); called by muse, mutect2
- PPHLN1 | c.860T>G p.L287R | Missense Mutation (SNP) | VAF 21/262 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.903); called by muse, mutect2
- REV3L | c.3055C>A p.P1019T | Missense Mutation (SNP) | VAF 27/234 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.382); called by muse, mutect2
- SPEM1 | c.893G>A p.S298N | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.124); called by muse, mutect2
- STYK1 | c.812G>A p.G271D | Missense Mutation (SNP) | VAF 68/748 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.951); called by muse, mutect2
- XAGE2 | c.52C>A p.Q18K | Missense Mutation (SNP) | VAF 104/290 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ADGRA3 | c.867G>A p.S289= | Silent (SNP) | VAF 19/174 reads (11%) | catalogued as rs778353681, COSV51566965; called by muse, mutect2, varscan2
- ARHGEF10L | c.3825G>C p.V1275= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV51438412; called by muse, mutect2
- C1orf116 | c.1107G>A p.K369= | Silent (SNP) | VAF 20/135 reads (15%) | catalogued as COSV63944547; called by muse, mutect2, varscan2
- CDH23 | c.7626A>T p.G2542= | Silent (SNP) | VAF 24/250 reads (10%) | catalogued as COSV56482673; called by muse, mutect2, varscan2
- CIT | c.4023G>A p.K1341= | Silent (SNP) | VAF 9/98 reads (9%) | catalogued as rs758137948; called by muse, mutect2
- CLPTM1L | c.1128C>A p.G376= | Silent (SNP) | VAF 24/217 reads (11%) | called by muse, mutect2, varscan2
- DNAJC16 | c.828G>T p.L276= | Silent (SNP) | VAF 69/176 reads (39%) | catalogued as COSV65449264; called by muse, mutect2, varscan2
- DPP3 | c.1338G>A p.Q446= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV64757675; called by muse, mutect2, varscan2
- GC | c.1170T>A p.P390= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV56739176; called by muse, mutect2, varscan2
- HKDC1 | c.234G>A p.G78= | Silent (SNP) | VAF 7/103 reads (7%) | catalogued as rs1287616492, COSV63577357; called by muse, mutect2
- KRTAP10-11 | c.150G>A p.V50= | Silent (SNP) | VAF 20/130 reads (15%) | catalogued as COSV58179101; called by muse, mutect2, varscan2
- MB21D2 | c.465G>A p.E155= | Silent (SNP) | VAF 27/259 reads (10%) | catalogued as COSV66665415; called by muse, mutect2, varscan2
- MEFV | c.189A>G p.E63= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV54825991; called by muse, mutect2, varscan2
- NCAPD3 | c.3831G>A p.G1277= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV73187938; called by muse, mutect2
- NEURL3 | c.675C>T p.Y225= | Silent (SNP) | VAF 9/101 reads (9%) | called by muse, mutect2
- OR7G1 | c.564C>A p.A188= | Silent (SNP) | VAF 40/275 reads (15%) | catalogued as COSV53318625; called by muse, mutect2, varscan2
- OXR1 | c.1503A>G p.E501= (on ENST00000442977 / NM_001198532.1; = p.E500= on NM_018002.3) | Silent (SNP) | VAF 40/67 reads (60%) | catalogued as COSV56334375; called by muse, mutect2, varscan2
- PRAMEF10 | c.1029G>A p.L343= | Silent (SNP) | VAF 42/452 reads (9%) | called by muse, mutect2
- RPP38 | c.804T>A p.P268= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV65382964; called by muse, mutect2, varscan2
- SLC6A3 | c.1083C>G p.G361= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV54368253; called by muse, mutect2
- SPRR2B | c.33C>A p.P11= | Silent (SNP) | VAF 28/364 reads (8%) | called by muse, varscan2
- SPRYD3 | c.492C>T p.T164= | Silent (SNP) | VAF 16/218 reads (7%) | called by muse, mutect2
- TLR7 | c.2205C>A p.I735= | Silent (SNP) | VAF 8/131 reads (6%) | called by muse, mutect2
- TRIML1 | c.33G>A p.R11= | Silent (SNP) | VAF 38/209 reads (18%) | catalogued as COSV60196275; called by muse, mutect2, varscan2
- ZBTB34 | c.687C>T p.S229= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV59860565; called by muse, mutect2
- EFCAB12 | chr3:129397294 C>A | 3'Flank (SNP) | VAF 23/185 reads (12%) | called by muse, mutect2, varscan2
- EFCAB12 | chr3:129397295 C>T | 3'Flank (SNP) | VAF 23/186 reads (12%) | called by muse, mutect2, varscan2
